Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6702, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6702-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Case ID		Subject ID	Formatted Path Report
[REDACTED]	[REDACTED]	[REDACTED]	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Abdominal perineal resection Specimen size: Not specified Tumor site: Rectosigmoid junction Tumor size: 0 x 0 x 3.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Subserosa Lymph nodes: 1/12 positive for metastasis (Adjacent fatty tissue 1/12) Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 968d7092-fcfb-4878-9fa8-024323c3d8f6 (TCGA-F5-6702.F8F83520-6F9E-446C-BCCA-F538A3AE1487.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).